Surgical pathology report (de-identified scan), TCGA case TCGA-06-6701, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-6701-01A (Primary Tumor).

[page 1 of 5]
TCGA-06-6701

Surgical Pathology Report

CLINICAL HISTORY

[REDACTED] has experienced [REDACTED] for about [REDACTED]
[REDACTED] On
imaging there is a large lesion involving left frontal lobe, basal
ganglia,
insula, and extending across the corpus callosum, and is minimally
enhancing.

OPERATIVE DIAGNOSES

Left brain mass

Operation/Specimen: A: Brain, left frontal tumor, biopsy
B: Brain, left frontal tumor, excision

PATHOLOGICAL DIAGNOSIS:

A and B. Brain, left frontal, excisional biopsy and excision:
Glioblastoma
(WHO IV).
See Microscopy Description and Comment.

COMMENT

The specimen is portions of cerebrum that are extensively and
moderately to
heavily infiltrated by a glial neoplastic proliferation. The
neoplastic cells
tend to have round or oval nuclei, and focally have a gemistocytic
phenotype.
Focally there is nuclear anaplasia and some mitotic activity, with a
MIB-1
proliferation index of 5% to 7% in the more active areas. There is
neovascularization throughout the tumor. Focally, there is also
microvascular
cellular proliferation with karyorrhexis, and one microscopic area of
tumor necrosis with pseudopalisading.

[page 2 of 5]
tumor necrosis with pseudopalisading.

The neoplasm is a high histological grade astrocytoma, perhaps with an oligodendroglial component. The larger portion of the neoplasm has an anaplastic phenotype; however, focally it has features of a glioblastoma:

microvascular cellular proliferation and tumor necrosis.

The tumor does not have 1p, 19q LOH (see Report below).

=====

PROCEDURES/ADDENDA

Loss of Heterozygosity 1p, 19q Assay (LOH)

Date Ordered: [REDACTED] Date Reported: [REDACTED]

Interpretation

NEGATIVE: Allelic loss on chromosome arm 1p and chromosome arm 19q is NOT detected.

Informative loci are: D1S548, D1S552, D19S219 and D19S412

Results-Comments

Testing was performed on DNA extracted from tumor paraffin block DNA extracted from a corresponding blood specimen was used as a normal reference control.

H slide was examined and no microdissection was needed.

TEST DESCRIPTION: Allelic loss is assessed by PCR assay in Normal DNA (baseline)/ Tumor DNA pairs using 3 markers at both 1p and 19q. The 3 markers on 1p are D1S548, D1S1592, and D1S552 (with D1S468, D1S1612, and D1S496 as backup markers) and the 3 markers on 19q are D19S219, D19S412, and PLA2G4C (with D19S606 and D19S1182 as backup). All markers are microsatellites (2 or 4 nt repeats) except PLA2G4C which is a minisatellite (26 nt repeat) polymorphism. The markers were selected based on heterozygosity score, amplicon size, and ease of interpretation. The backup markers are used if the first line markers at that chromosome arm are uninformative or otherwise ambiguous in their interpretation. LOH at all informative loci on each chromosomal arm represents the typical finding in oligodendrogliomas with 1p and 19q deletion.

[page 3 of 5]
FDA COMMENT: The above data are not to be construed as the results from a stand-alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA ' [REDACTED] regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

TECHNICAL SENSITIVITY: The presence of >15% non-neoplastic cells in the sample may preclude the detection of allelic loss.

Interpretation

NEGATIVE: No evidence of methylated MGMT promoter is detected.

Results-Comments

Testing performed on DNA extracted from tumor paraffin block

H slide was examined and no microdissection was needed.

TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter

have been shown to benefit from therapy with alkylating agents.

Assessment of

MGMT promoter methylation status involves bisulfite treatment of DNA followed

by real-time PCR amplification (MethyLight) of methylated and unmethylated DNA

sequences. The analytic sensitivity of this assay was determined by serial

dilution of methylated positive control DNA into unmethylated DNA, and was

assessed to be 1% of methylated DNA in the background of unmethylated DNA.

Factors such as the presence of >50% non-neoplastic cells in the sample, or

extensive tissue necrosis, may preclude the detection of methylated MGMT promoter sequences.

[page 4 of 5]
FDA COMMENT: The above data are not to be construed as the results from a stand alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA ' [REDACTED] regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

[REDACTED]

=====

INTRA-OPERATIVE CONSULTATION

A.

Brain, left frontal tumor, biopsy: Glioma, high histological grade? (C/W glioblastoma; R/O oligo component). [REDACTED] Touch preparation smears performed at [REDACTED] Hospital and results reported to the Physician of [REDACTED] Record. [REDACTED]

[REDACTED]

GROSS DESCRIPTION

A.

"Left frontal tumor," received fresh, four fragments, 0.8 cm in aggregate. Semi-firm, pinkish grey, glistening, somewhat diffluent. In total, A1 and A2.

B.

Brain, left frontal tumor, excision.

CONTAINER LABEL: Left frontal tumor

FIXATIVE: Fresh. NO. PIECES: multiple pink-red, glistening tissue fragments.

SIZE/VOL: 6.0 x 5.5 x 1.5 cm. CASSETTES: 5 [REDACTED] [REDACTED]

[REDACTED]

MICROSCOPIC DESCRIPTION

[page 5 of 5]
IMMUNOHISTOCHEMISTRY: The GFAP demonstrates a gliofibrillary background in the infiltrative areas, and heavy gliofibrillogenesis in gemistocytic zones.

A great majority of neoplastic cells over expresses the p53 protein. The CD34

demonstrates focally microvascular cellular proliferation (glomeruloid-like).

With the MIB-1 there is a proliferation index of about 7% in the more active areas.

ICD-9(s):

191.9 191.9

Histo Data

Part A: Brain, left frontal tumor, biopsy

Taken:	Received:		
Stain/cnt	Block	Ordered	Comment
H/E x 1	1		
TPS H/E x 1	1		
H/E x 1	2		

Part B: Brain, left frontal tumor, excision

Taken:	Received:		
Stain/cnt	Block	Ordered	Comment
H/E x 1	1		
H/E x 1	2		
LOH-curls x 1	2		
MGMT-curls x 1	2		
H/E x 1	3		
CD34-DA x 1	4		
mGFAP-DA x 1	4		
H/E x 1	4		
MIB1-DA x 1	4		
P53DO7 x 1	4		
CD34-DA x 1	5		
H/E x 1	5		
MIB1-DA x 1	5		

1p, 19q. Thanks.

*** End of Report ***

Source: NCI Genomic Data Commons file 649a7ee8-e991-4f8c-9a6b-b1dcf4363729 (TCGA-06-6701.A124F2D0-F289-4A57-84B6-051BA2C3736F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).